Somatic mutation profile of tumor specimen C3L-01256-01 (aliquot CPT0073450009) from CPTAC case C3L-01256, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 75.2 years (27,474 days).
Specimen C3L-01256-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a44f4029-0949-4a94-bc49-8d41f50ccd47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01256-71 (Blood Derived Normal), aliquot CPT0073470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4da0496-5a69-47ee-8517-5e87a2b47a31

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769370816, CD099865, CM983630, CM983631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.987_990del p.N329Kfs*14 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs587782304; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AKAIN1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as rs745657091, COSV71420513; called by muse, mutect2, varscan2
- C3orf20 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs747416838; called by muse, mutect2, varscan2
- CLBA1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs944652275; called by muse, mutect2
- CYBA | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs779140893, CD064540; called by muse, mutect2, varscan2
- DOCK8 | c.3637G>A p.A1213T | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1172637555, COSV101209763; called by muse, mutect2
- E2F1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 45/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535777; called by muse, mutect2, varscan2
- EIF4A1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1244960491; called by muse, mutect2
- FAM193A | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751073575; called by muse, mutect2
- INAVA | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV66256453; called by muse, mutect2, varscan2
- KDM5C | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 36/292 reads (12%) | catalogued as COSV64762891; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2597G>C p.R866P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV56620530; called by muse, mutect2
- NCKAP1L | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752125351, COSV53203384; called by muse, mutect2
- PCLO | c.14672G>A p.R4891H | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376928297; called by muse, mutect2
- PRR23C | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs1339815303, COSV101356458; called by muse, mutect2, varscan2
- RUNX1 | c.218C>T p.S73F (on ENST00000344691 / NM_001001890.3; = p.S100F on NM_001754.5) | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55868630, COSV55869047; called by muse, mutect2, varscan2
- SPTBN1 | c.2384A>G p.N795S | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs757348488; called by muse, mutect2
- TJP2 | c.3364A>G p.I1122V | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs920690938; called by muse, mutect2
- VIRMA | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1406397311; called by muse, mutect2
- BMP5 | c.17T>G p.F6C | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.045); called by muse, mutect2
- C3orf20 | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DGKE | c.1473T>G p.I491M | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH10 | c.2129C>T p.A710V (on ENST00000409039; = p.A649V on NM_207437.3) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- GAB3 | c.468G>T p.L156F | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- KMT2D | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- LIMK1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAP3K1 | c.2504C>A p.S835* | Nonsense Mutation (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- MTHFSD | c.406T>G p.L136V (on ENST00000360900 / NM_001159377.2; = p.L135V on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTOR | c.4556C>T p.A1519V | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- OIT3 | c.788_790+13del p.X263_splice | Splice Site (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- OR2L5 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PCDH11X | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PIK3R2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- RGS12 | c.1998+8A>T | Splice Region (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- SLCO6A1 | c.141del p.K47Nfs*5 | Frame Shift Del (DEL) | VAF 26/286 reads (9%) | called by mutect2, pindel
- ZKSCAN1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM2 | c.2255A>G p.E752G | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- ASPDH | c.528C>T p.Y176= (on ENST00000389208 / NM_001114598.2; = p.Y71= on NM_001024656.3) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1437903400, COSV65350250; called by muse, mutect2
- CD5L | c.921C>T p.R307= | Silent (SNP) | VAF 30/338 reads (9%) | called by muse, mutect2
- CHRD | c.1950A>G p.Q650= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- GDF7 | c.726G>A p.P242= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs899756164; called by muse, mutect2, varscan2
- IFNGR2 | c.297C>T p.A99= | Silent (SNP) | VAF 68/593 reads (11%) | catalogued as rs754424181; called by muse, mutect2, varscan2
- KCNC3 | c.1254C>T p.F418= | Silent (SNP) | VAF 51/468 reads (11%) | catalogued as rs147343947; called by muse, mutect2, varscan2
- MTERF3 | c.771A>G p.R257= | Silent (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- OR5H15 | c.795G>A p.P265= | Silent (SNP) | VAF 15/220 reads (7%) | catalogued as rs371915983; called by muse, mutect2
- PPP1R3A | c.1536C>A p.G512= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- PPP5C | c.252C>T p.D84= | Silent (SNP) | VAF 24/330 reads (7%) | catalogued as rs146403367; called by muse, mutect2
- SGCZ | c.486G>A p.R162= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as rs1376386740, COSV66016487; called by muse, mutect2
- TTYH3 | c.1467C>T p.T489= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs977350570; called by muse, mutect2, varscan2
- NPEPL1 | c.1001+89G>A | Intron (SNP) | VAF 30/281 reads (11%) | catalogued as rs188994981; called by muse, mutect2, varscan2
- TANK | c.1101+1237A>T | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- UNK | c.-53C>A | 5'UTR (SNP) | VAF 14/160 reads (9%) | catalogued as rs371296829; called by muse, mutect2
